Surgical pathology report (de-identified scan), TCGA case TCGA-UY-A78P, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UY-A78P-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Carcinoma, urothelial
8/20/13
Site: Bladder NOS
C67.9
JW 8/20/13

Clinical Diagnosis/History:

The patient is a 60-year-old woman who presented in hematuria. She underwent a transurethral resection of a high-grade muscle invasive transitional cell carcinoma of the bladder. The patient now undergoes a radical cystectomy with resection of the uterus, vagina, bilateral tubes and ovaries. with gross Per TSS, TURBT was performed on this TCGA tumor. BCR

Gross Description:

The specimen is received in seven parts, each labeled with the patient's name and medical record number. Parts A-C are received fresh. Parts D-G are received in formalin.

Part A, additionally labeled "1 - right distal ureteral margin FS," consists of a single white-tan segment of ureter that measures 0.5 x 0.4 x 0.3 cm. The specimen is entirely submitted for frozen section diagnosis as FS1, with the remnant tissue submitted in cassette A1.

Part B, additionally labeled "3 - left distal ureteral margin FS," consists of a single white-tan segment of ureter and fibroadipose tissue that measures 1.2 x 0.4 x 0.3 cm. The ureter only is submitted for frozen section diagnosis as FS2, with the remnant tissue submitted in cassette B1. The remainder of the specimen is submitted in cassette B2.

Part C is additionally labeled "bladder, uterus, ovaries, portion of vagina." and consists of bladder, uterus, adnexae and vagina. The entire specimen weighs 385 grams. The bladder measures 7.5 x 7 x 2 cm. The tumor measures 2.0 x 2.5 cm and extends 1.0 cm in depth and is right adjacent to the right ureteral orifice; it is confined to the bladder. There is no invasion beyond the bladder wall. The tumor is 5 cm distance from the urethral margin. The bladder mucosa is gray-brown with small and edematous. No further ulcerations, polyps or masses can be visualized or palpated. The urethra measures 3.5 in length and 1.5 cm in diameter. The right ureter measures 1.5 x 0.5 cm, the left ureter measures 1.3 x 0.5 cm. The vaginal cuff measures 0.9 cm in greatest dimension, the uterus measures 9 cm from fundus to cervix, 6.5 cm from cornu to cornu, 2.5 cm from anterior to posterior. The right ovary measures 3 x 2 x 1 cm, the left ovary measures 3.0 x 2.4 x 1.0 cm. The right ovary reveals corpora lutea on cut section, the left ovary reveals a white rim on cut section. The

[page 2 of 3]
right fallopian tube measures 2.5 x 0.5 cm, the left fallopian tube measures 4.0 x 0.5 cm. The cervix is opened in the frontal plane, the cervix shows nabothian cysts, but no other lesions are found. The endometrium measures 0.1 cm and the myometrium measures 1.5 cm.

Cassette submission:

Cassette C1: Right ureteral margin en face.

Cassette C2: Left ureteral margin en face.

Cassette C3: The urethral margin is inked green and perpendicular sections from 12-3 o'clock are submitted.

Cassette C4: Perpendicular sections of urethral margin 3-6 o'clock.

Cassette C5: Perpendicular sections from urethral margin 6-9 o'clock.

Cassette C6: Urethral margin, perpendicular section 9-12 o'clock.

Cassette C7: Perpendicular sections of vaginal cuff (multiple representative sections).

Cassette C8: Full-thickness sections of bladder, tumor and cervix demonstrating their relationship.

Cassette C9: Tumor in relationship to right ureter.

Cassette C10: Tumor (the tumor is entirely submitted).

Cassette C11: Representative sections of the bladder trigone.

Cassette C12: Representative sections of right bladder.

Cassette C13: Representative sections of left bladder.

Cassette C14: Anterior cervix.

Cassette C15: Posterior cervix.

Cassette C16: Anterior endomyometrium.

Cassette C17: Posterior endomyometrium.

Cassette C18: Right ovary and fallopian tube.

Cassette C19: Left ovary and fallopian tube.

Cassette C20: Two candidate lymph nodes.

Part D, labeled "right pelvic lymph node," consists of a single soft, irregular piece of yellow-brown, fatty tissue measuring 7 x 6.5 x 1.2 cm. The specimen is examined for candidate lymph nodes. Multiple candidate lymph nodes are found, ranging from 0.2 to 2.5 cm in greatest dimension. Candidate lymph nodes are submitted as follows:

Cassette D1: Three whole nodes.

Cassette D2: One node, bisected.

Cassette D3: Multiple whole nodes.

Cassette D4: One node, bisected.

Cassette D5: Multiple whole nodes.

Cassette D6: One node, bisected.

Cassettes D7-D8: One node, bisected.

The remaining tissue is returned to the container.

Part E, labeled "left pelvic lymph node," consists of multiple soft, irregular pieces of yellow-brown, fatty tissue measuring 7 x 4.8 x 2.5 cm in aggregate. Multiple candidate lymph nodes are found, ranging from 0.1 to 2.5 cm in greatest dimension. Candidate lymph nodes are submitted as follows:

Cassette E1: Multiple whole nodes.

Cassettes E2-E3: One node, bisected.

Cassette E4: One node, bisected.

Cassette E5: One node, bisected.

Cassette E6: Two nodes, one bisected.

Cassette E7: Two whole nodes.

Cassettes E8-E9: One node bisected.

The remaining tissue is returned to the container.

Part F, labeled "distal left ureter," consists of a single soft, roughly

[page 3 of 3]
tubular piece of yellow-brown tissue measuring 1.3 cm in length with a diameter of 0.4 cm. The specimen is unoriented; the two end margins are inked blue. The specimen is cross-sectioned and submitted in cassette F1. There is remaining tissue, consisting of two fragments of soft, irregular, yellow-brown fat, measuring 2 x 1 x 0.2 cm. These remaining fragments are entirely submitted in cassette F2.

Part G, labeled "distal right ureter," consists of a single soft, unoriented, roughly tubular piece of brown-tan/white tissue measuring 1.5 cm in length with a diameter of 0.5 cm. The end margins are inked blue. The specimen is serially cross-sectioned and entirely submitted, with the end margins in cassette G1 and the central portion in cassette G2.

Diagnosis Comments:

Bladder Tumor Synoptic Comment

1. Tumor type: Urothelial (transitional cell).
2. Tumor grade: High grade.
3. Tumor size: 2.5cm.
4. Extent of tumor in bladder: Invasion into outer half of muscularis propria.
5. Lymphatic/vascular invasion: None identified.
6. Epithelial abnormalities in bladder: None identified.
7. Extension of tumor into organs adjacent to bladder: No adjacent organs involved.
8. Surgical margins: Free of tumor.
9. Lymph nodes: 0 of 20 lymph nodes contain metastatic tumor;
10. Other pathologic findings in bladder: None identified.
11. AJCC/UICC stage: pT2bN0Mx.

Interoperative Diagnosis:

FS1 (A) Right distal ureteral margin, biopsy: No tumor seen. [REDACTED]

FS2 (B) Left distal ureteral margin, biopsy: No tumor seen. [REDACTED]

Final Diagnosis:

- A. Right distal ureteral margin, excision: No tumor.
- B. Left distal ureteral margin, excision: No tumor.
- C. Bladder, uterus, adnexae, en-bloc resection:
- Bladder: Invasive urothelial carcinoma, high-grade, invading muscularis propria; negative surgical margins; see comment.
- Endometrium: Atrophic.
- Myometrium: No significant pathologic abnormality.
- Uterine serosa: No significant pathologic abnormality.
- Cervix: No significant pathologic abnormality.
- Ovaries: Inclusion cysts.
- Tubes: No significant pathologic abnormality.
- D. Right pelvic lymph nodes, dissection: No tumor (0/10).
- E. Left pelvic lymph nodes, dissection: No tumor (0/10).
- F. Distal left ureter, resection: No tumor.

Qual. Synchronous Primary Notation		

Source: NCI Genomic Data Commons file 8528e16c-d6d0-49da-aee4-23a772e098ce (TCGA-UY-A78P.89019149-B6D2-4540-9BFE-BACCA9F5DA14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).